Somatic mutation profile of tumor specimen TCGA-V4-A9EW-01A (aliquot TCGA-V4-A9EW-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EW, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 44.2 years (16,140 days).
Specimen TCGA-V4-A9EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc66457b-f8f6-4441-8305-89b094b4e567.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EW-10A (Blood Derived Normal), aliquot TCGA-V4-A9EW-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/958a8539-988c-43cb-bb8c-71a97256ba72

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 35/88 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACP2 | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs762176748; called by muse, mutect2, varscan2
- CNTN5 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370172429; called by muse, mutect2, varscan2
- DCAF11 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs777653791; called by muse, mutect2, varscan2
- PRAMEF20 | c.1348A>T p.I450F | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs900978963; called by muse, mutect2, varscan2
- SLC5A12 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.23); catalogued as rs1291728602; called by muse, mutect2, varscan2
- PKHD1L1 | c.10059_10073del p.F3353_G3357del | In Frame Del (DEL) | VAF 8/73 reads (11%) | called by mutect2, pindel
- CNST | c.1923A>G p.P641= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs1001635740; called by muse, mutect2, varscan2
- LCAT | c.723C>T p.I241= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- RUNDC1 | c.1416G>A p.P472= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs749457403; called by muse, mutect2, varscan2
- ZFYVE19 | c.171A>G p.P57= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1193218587; called by muse, mutect2, varscan2
